Somatic mutation profile of tumor specimen TARGET-50-PAKXWB-01A (aliquot TARGET-50-PAKXWB-01A-01D) from TARGET case TARGET-50-PAKXWB, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,681 days).
Specimen TARGET-50-PAKXWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ecad0e-110b-4f9f-94f3-c23897ea4ddc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKXWB-10A (Blood Derived Normal), aliquot TARGET-50-PAKXWB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b404237-76f1-4199-9cad-3790cc5ff063

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIP2C | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99789545; called by muse, mutect2
- PADI3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs34341567, COSV64934181; called by muse, mutect2, varscan2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2, varscan2
- RAET1L | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 143/460 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764834911; called by muse, varscan2
- SCG2 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs368049148; called by muse, mutect2, varscan2
- ZYG11A | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 204/467 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); catalogued as COSV65292462, COSV65293869; called by muse, mutect2, varscan2
- ATP6AP1 | c.324_325del p.F109Wfs*10 | Frame Shift Del (DEL) | VAF 20/206 reads (10%) | called by pindel, varscan2
- MED12 | c.110_118del p.T37_L39del | In Frame Del (DEL) | VAF 55/136 reads (40%) | called by mutect2, pindel, varscan2
- NUMA1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RAET1G | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 140/1352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RBM10 | c.461_471del p.V154Gfs*22 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- USP49 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ACVR1C | c.888G>A p.A296= | Silent (SNP) | VAF 104/318 reads (33%) | catalogued as rs760426734, COSV54648581; called by muse, mutect2, varscan2
- CNTNAP4 | c.3207C>A p.I1069= | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as COSV100269205, COSV56671446, COSV56671531; called by muse, mutect2, varscan2
- DST | c.4297-4434C>T | Intron (SNP) | VAF 20/307 reads (7%) | catalogued as rs370145993; called by muse, mutect2
